Somatic mutation profile of tumor specimen TCGA-13-1494-01A (aliquot TCGA-13-1494-01A-01W-0545-08) from TCGA case TCGA-13-1494, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 43.8 years (15,993 days).
Specimen TCGA-13-1494-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8174086-d5e4-4a71-8d6c-07e2ea02cc45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1494-10A (Blood Derived Normal), aliquot TCGA-13-1494-10A-01W-0545-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27cfba6c-5ff8-4804-b44a-683922e8c981

The open-access MAF lists 74 somatic variants for this specimen: 54 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 19, Nonsense Mutation 5, In Frame Del 5, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 173/450 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, mutect2, varscan2
- ABL2 | c.676G>A p.A226T (on ENST00000502732 / NM_007314.4; = p.A211T on NM_005158.5) | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV61019516; called by muse, mutect2, varscan2
- ANO6 | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57665507; called by muse, mutect2, varscan2
- ATP6V1C2 | c.366C>A p.D122E | Missense Mutation (SNP) | VAF 12/329 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.028); catalogued as COSV99695815; called by muse, mutect2
- BCORL1 | c.4132C>A p.L1378I | Missense Mutation (SNP) | VAF 134/532 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54404390; called by muse, mutect2, varscan2
- BMPR2 | c.2651T>C p.L884P | Missense Mutation (SNP) | VAF 288/1936 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.854); catalogued as COSV65812807; called by muse, mutect2, varscan2
- CCDC120 | c.1487G>A p.S496N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as rs1557081866, COSV64481637; called by muse, mutect2, varscan2
- CD248 | c.1949G>T p.G650V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV60935819, COSV60937595; called by muse, mutect2, varscan2
- CDHR2 | c.2788C>T p.P930S | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); catalogued as COSV56141382, COSV56143747; called by muse, mutect2, varscan2
- COA7 | c.272C>A p.A91D | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.334); catalogued as COSV101034374; called by muse, mutect2
- COL17A1 | c.2770G>T p.G924C | Missense Mutation (SNP) | VAF 91/229 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62228866; called by muse, mutect2, varscan2
- COL6A3 | c.5182G>T p.V1728L | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55104376; called by muse, mutect2, varscan2
- CPS1 | c.386C>A p.S129* | Nonsense Mutation (SNP) | VAF 15/406 reads (4%) | catalogued as COSV99243144; called by muse, mutect2
- CSGALNACT2 | c.1246C>A p.Q416K | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV65676271; called by muse, mutect2, varscan2
- CYP2A7 | c.655C>A p.L219I | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.592); catalogued as rs145739973; called by muse, mutect2, varscan2
- DCAF12L1 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 53/163 reads (33%) | catalogued as COSV64421493, COSV64422607; called by muse, mutect2, varscan2
- DNTTIP2 | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 59/224 reads (26%) | catalogued as COSV63284486; called by muse, varscan2
- EPHX1 | c.776C>A p.T259N | Missense Mutation (SNP) | VAF 34/1072 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.232); catalogued as COSV99689007; called by muse, mutect2
- FAT4 | c.6568C>A p.R2190S | Missense Mutation (SNP) | VAF 42/782 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV100628797; called by muse, mutect2
- FCRL1 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 151/500 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.959); catalogued as COSV63826893; called by muse, mutect2, varscan2
- FMNL3 | c.1009A>G p.M337V | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV99526402; called by muse, mutect2, varscan2
- GOLGB1 | c.2494C>G p.L832V | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.543); catalogued as COSV61469737; called by muse, mutect2, varscan2
- GPR137 | c.206G>A p.W69* | Nonsense Mutation (SNP) | VAF 11/192 reads (6%) | catalogued as COSV100464284; called by muse, mutect2
- IGSF10 | c.5173G>A p.A1725T | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779602494, COSV56789051; called by muse, mutect2, varscan2
- IL13 | c.5A>G p.H2R | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs778963746, COSV100449410; called by muse, mutect2, varscan2
- KLKB1 | c.167G>A p.R56K | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.149); catalogued as COSV52998477; called by muse, mutect2, varscan2
- KRTAP19-1 | c.218A>T p.Y73F | Missense Mutation (SNP) | VAF 268/744 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as COSV101185829; called by muse, varscan2
- LCOR | c.3637G>A p.V1213I | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.928); catalogued as COSV53717933; called by muse, mutect2, varscan2
- LRP12 | c.163C>G p.R55G | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as rs777398485, COSV52633496; called by muse, mutect2, varscan2
- MPHOSPH10 | c.41G>C p.C14S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54906907; called by muse, mutect2, varscan2
- MSX1 | c.536T>G p.F179C | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66947742; called by muse, mutect2, varscan2
- NUP37 | c.124A>G p.N42D | Missense Mutation (SNP) | VAF 375/529 reads (71%) | SIFT tolerated (0.65); PolyPhen benign (0.021); catalogued as COSV51839012; called by muse, mutect2, varscan2
- PEAR1 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs139898840, COSV52775265; called by muse, mutect2, varscan2
- PGAP2 | c.584_586del p.F195del (on ENST00000463452 / NM_001346398.2; = p.F256del on NM_014489.4) | In Frame Del (DEL) | VAF 43/353 reads (12%) | catalogued as rs777098385; called by pindel, varscan2
- PLA2G12B | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.966); catalogued as COSV65979066; called by muse, mutect2, varscan2
- RAB40B | c.674_676del p.F225del | In Frame Del (DEL) | VAF 39/144 reads (27%) | catalogued as rs1305555523; called by mutect2, pindel, varscan2
- RASAL1 | c.1178C>T p.T393I | Missense Mutation (SNP) | VAF 54/621 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.219); catalogued as COSV99921793; called by muse, mutect2
- RNF43 | c.437C>G p.A146G | Missense Mutation (SNP) | VAF 501/709 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV68459818; called by muse, mutect2, varscan2
- SH3TC2 | c.3209C>A p.A1070D | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100101776; called by muse, mutect2
- SLC6A3 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 153/534 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs751595931, COSV54368468; called by muse, mutect2, varscan2
- TEX14 | c.3392A>T p.Q1131L (on ENST00000240361 / NM_001201457.2; = p.Q1085L on NM_031272.5) | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.617); catalogued as COSV99542424; called by muse, mutect2
- TMEM132A | c.1525G>T p.V509F (on ENST00000453848 / NM_178031.3; = p.V510F on NM_017870.4) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV50018532; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1417C>A p.Q473K | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.074); catalogued as COSV54871440; called by muse, mutect2, varscan2
- TRAK2 | c.2333C>T p.P778L | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60274290; called by muse, mutect2, varscan2
- TTLL8 | c.722C>A p.A241D | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56722078; called by muse, mutect2, varscan2
- USP22 | c.443G>A p.W148* | Nonsense Mutation (SNP) | VAF 8/248 reads (3%) | catalogued as rs1485471840; called by muse, mutect2
- WIPI1 | c.1295T>C p.I432T | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV100048441; called by muse, mutect2
- WRNIP1 | c.1775A>T p.E592V | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV66356323; called by muse, mutect2, varscan2
- ZHX3 | c.1656G>T p.L552F | Missense Mutation (SNP) | VAF 24/301 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV100476168; called by muse, mutect2
- ZNF438 | c.1046C>A p.P349Q | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as COSV100062051; called by muse, mutect2
- KRTAP19-1 | c.226_228del p.C76del | In Frame Del (DEL) | VAF 191/567 reads (34%) | called by pindel, varscan2
- MCM4 | c.118_145del p.E40Sfs*42 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | called by mutect2, pindel
- MYO9A | c.4622_4642del p.C1541_S1547del | In Frame Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- RCOR2 | c.560_580del p.D187_L193del | In Frame Del (DEL) | VAF 13/30 reads (43%) | called by mutect2, pindel, varscan2
- ACACA | c.2304G>A p.V768= | Silent (SNP) | VAF 14/362 reads (4%) | called by muse, mutect2
- ACAD10 | c.2178A>G p.K726= | Silent (SNP) | VAF 29/189 reads (15%) | catalogued as COSV58161768; called by muse, mutect2, varscan2
- ATP2B2 | c.1275C>T p.Y425= (on ENST00000352432; = p.Y391= on NM_001683.5) | Silent (SNP) | VAF 31/233 reads (13%) | catalogued as rs371159930; called by muse, mutect2, varscan2
- BCL2L13 | c.948C>T p.P316= | Silent (SNP) | VAF 70/246 reads (28%) | catalogued as rs769593795, COSV58227183; called by muse, mutect2, varscan2
- CACNA2D4 | c.2757C>G p.V919= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV54957846; called by muse, mutect2
- CHMP7 | c.1308C>T p.V436= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as rs753176661, COSV57533717; called by muse, mutect2, varscan2
- ELP1 | c.3168G>C p.L1056= | Silent (SNP) | VAF 241/463 reads (52%) | catalogued as COSV65899423; called by muse, mutect2, varscan2
- EPS8L1 | c.1620G>A p.L540= (on ENST00000201647 / NM_133180.3; = p.L413= on NM_017729.3) | Silent (SNP) | VAF 64/170 reads (38%) | catalogued as rs1400165773, COSV52385297; called by muse, varscan2
- EXOC2 | c.2109C>T p.F703= | Silent (SNP) | VAF 29/144 reads (20%) | catalogued as rs1554127363, COSV57870595; called by muse, mutect2, varscan2
- FBXO6 | c.561G>T p.L187= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV99335986; called by muse, mutect2
- ITK | c.1623G>A p.V541= | Silent (SNP) | VAF 186/422 reads (44%) | catalogued as COSV70064784; called by muse, mutect2, varscan2
- LPAR4 | c.492C>A p.I164= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as COSV70913264; called by muse, mutect2, varscan2
- MICAL1 | c.2119C>T p.L707= | Silent (SNP) | VAF 48/340 reads (14%) | catalogued as COSV57806719; called by muse, mutect2, varscan2
- PAH | c.1041C>T p.L347= | Silent (SNP) | VAF 284/482 reads (59%) | catalogued as rs1233192488, COSV61019602; called by muse, varscan2
- SLC30A4 | c.720T>C p.G240= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV99970277; called by muse, mutect2
- TCF4 | c.180G>A p.G60= | Silent (SNP) | VAF 92/1294 reads (7%) | catalogued as rs151203913; called by muse, mutect2
- TECTA | c.3489G>A p.V1163= | Silent (SNP) | VAF 22/721 reads (3%) | catalogued as COSV99880072; called by muse, mutect2
- TNN | c.138C>T p.Y46= | Silent (SNP) | VAF 24/654 reads (4%) | catalogued as COSV99512108; called by muse, mutect2
- UGT1A3 | c.720G>A p.Q240= | Silent (SNP) | VAF 393/1012 reads (39%) | catalogued as COSV100529446, COSV100530334; called by muse, mutect2, varscan2
- CA6 | c.259+2057G>T | Intron (SNP) | VAF 47/147 reads (32%) | catalogued as COSV101077563; called by muse, mutect2, varscan2
